Somatic mutation profile of tumor specimen TARGET-10-PAPZPJ-09A (aliquot TARGET-10-PAPZPJ-09A-01D) from TARGET case TARGET-10-PAPZPJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,484 days).
Specimen TARGET-10-PAPZPJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 184a334e-190d-4e9a-ba6c-5c8cf673c05d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZPJ-14A (Bone Marrow Normal), aliquot TARGET-10-PAPZPJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e82a0833-2e4a-4d4a-b905-c9254f6ff61e

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 64/139 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFAP46 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1426436781, COSV63955960; called by muse, mutect2, varscan2
- ITGA3 | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs755058557; called by muse, varscan2
- JARID2 | c.3145C>A p.R1049S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.1); catalogued as COSV59200270; called by muse, mutect2
- LRRC66 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV58633082; called by muse, mutect2, varscan2
- NKX2-3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60728472; called by muse, mutect2
- PLCL1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs368374568; called by muse, mutect2, varscan2
- TMEM132B | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs201518513; called by muse, mutect2, varscan2
- IL2RA | c.250A>C p.S84R | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ROBO3 | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.5753C>T p.A1918V (on ENST00000367255 / NM_182961.4; = p.A1925V on NM_033071.3) | Missense Mutation (SNP) | VAF 86/315 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- YIPF7 | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- CECR2 | c.825C>A p.L275= (on ENST00000342247 / NM_001290047.2; = p.L112= on NM_001290046.1) | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99379249; called by muse, mutect2
- FAM205A | c.2061C>A p.I687= | Silent (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- KCNK15 | c.783C>G p.P261= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs756177503, COSV65719575; called by mutect2, varscan2
- KCNQ3 | c.978G>A p.T326= | Silent (SNP) | VAF 85/190 reads (45%) | catalogued as rs751628183, COSV66464302, COSV66472679; called by muse, mutect2, varscan2
- PCDHGA5 | c.708C>T p.N236= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- PPFIA3 | c.330G>A p.R110= | Silent (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.1575C>T p.N525= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs142490331; called by muse, mutect2, varscan2
- ATP6AP2 | c.*43C>A | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- KRAS | c.*8G>A | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
